Somatic mutation profile of tumor specimen TARGET-40-0A4I48-01A (aliquot TARGET-40-0A4I48-01A-01D) from TARGET case TARGET-40-0A4I48, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.0 years (5,854 days).
Specimen TARGET-40-0A4I48-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b247c0f4-9e24-4a2a-86b4-5693ada0d6f2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4I48-10A (Blood Derived Normal), aliquot TARGET-40-0A4I48-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/764d5697-66d7-4ece-b864-e7d8cb005343

The open-access MAF lists 44 somatic variants for this specimen: 27 protein-altering or splice-affecting, 11 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 11, RNA 4, Nonsense Mutation 3, Splice Site 2, Intron 2, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA9 | c.3126G>T p.M1042I | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.483); catalogued as COSV100382816; called by muse, mutect2, varscan2
- C6orf15 | c.339G>C p.E113D | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.203); catalogued as COSV99456855; called by muse, mutect2, varscan2
- CEP295NL | c.1622_1625del p.E541Gfs*12 | Frame Shift Del (DEL) | VAF 19/68 reads (28%) | catalogued as rs1395357221; called by mutect2, pindel, varscan2
- COMMD3-BMI1 | c.142C>A p.H48N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.058); catalogued as rs762505507; called by muse, mutect2, varscan2
- HSD17B4 | c.1270A>G p.I424V (on ENST00000414835 / NM_001199291.3; = p.I399V on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV56334555; called by muse, mutect2, varscan2
- LILRA1 | c.455G>C p.G152A | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV52184502; called by muse, mutect2, varscan2
- MUC3A | c.7955T>C p.L2652P | Missense Mutation (SNP) | VAF 81/447 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.001); catalogued as rs1412395240; called by muse, mutect2, varscan2
- PCDH15 | c.5636C>A p.P1879Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.388); catalogued as rs1338012767; called by muse, mutect2, varscan2
- PLA2G2D | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs62541901; called by muse, mutect2, varscan2
- SHISA6 | c.1072C>T p.R358* (on ENST00000409168 / NM_001173461.1; = p.R409* on NM_207386.4) | Nonsense Mutation (SNP) | VAF 20/40 reads (50%) | catalogued as COSV69385996; called by muse, varscan2
- TP53 | c.365_366del p.V122Dfs*26 | Frame Shift Del (DEL) | VAF 24/56 reads (43%) | catalogued as rs587780067; called by pindel, varscan2
- ARRDC3 | c.169G>T p.V57L | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- COL11A2 | c.3680C>T p.P1227L (on ENST00000341947 / NM_080680.3; = p.P1120L on NM_080679.2) | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.186); called by muse, varscan2
- CSMD2 | c.801-2A>T p.X267_splice | Splice Site (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- EPB41L3 | c.2939C>A p.T980N | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EXOC2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- GRID1 | c.1211C>A p.T404N | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- NUDT21 | c.152A>C p.E51A | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, mutect2
- OXGR1 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PPP1R3A | c.757A>T p.K253* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- PXDN | c.922C>T p.Q308* | Nonsense Mutation (SNP) | VAF 34/230 reads (15%) | called by muse, varscan2
- RYR2 | c.293G>T p.W98L | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.177); called by muse, mutect2
- RYR2 | c.6299G>T p.R2100L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- STON2 | c.526G>C p.A176P | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- THOC5 | c.1723_1725del p.S575del | In Frame Del (DEL) | VAF 26/96 reads (27%) | called by pindel, varscan2
- TIGD2 | c.1491C>A p.D497E | Missense Mutation (SNP) | VAF 6/67 reads (9%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.874); called by muse, mutect2
- ZNF43 | c.131-1G>A p.X44_splice | Splice Site (SNP) | VAF 13/90 reads (14%) | called by muse, mutect2, varscan2
- ALLC | c.801A>G p.A267= | Silent (SNP) | VAF 23/131 reads (18%) | called by muse, mutect2, varscan2
- C2orf42 | c.1002G>A p.L334= | Silent (SNP) | VAF 31/153 reads (20%) | called by muse, mutect2, varscan2
- COL11A1 | c.2238T>A p.A746= | Silent (SNP) | VAF 10/96 reads (10%) | called by muse, mutect2
- EXOC2 | c.1254G>A p.L418= | Silent (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- GRM4 | c.270A>C p.I90= | Silent (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
- KCNC1 | c.738C>G p.T246= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- NID1 | c.2574G>C p.G858= | Silent (SNP) | VAF 8/25 reads (32%) | called by muse, mutect2, varscan2
- NRROS | c.2004T>A p.T668= | Silent (SNP) | VAF 22/195 reads (11%) | called by muse, mutect2, varscan2
- OR56B4 | c.873C>A p.L291= | Silent (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- SLC17A6 | c.321G>T p.G107= | Silent (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- TPR | c.3984A>G p.L1328= | Silent (SNP) | VAF 9/75 reads (12%) | called by muse, mutect2, varscan2
- CEP170P1 | n.1304G>T | RNA (SNP) | VAF 23/92 reads (25%) | called by muse, mutect2, varscan2
- DNM1P47 | n.1259G>A | RNA (SNP) | VAF 7/48 reads (15%) | catalogued as rs867904187; called by mutect2, varscan2
- EEF1A1P9 | n.106A>G | RNA (SNP) | VAF 28/53 reads (53%) | called by muse, mutect2, varscan2
- HNRNPCP2 | n.105A>T | RNA (SNP) | VAF 25/104 reads (24%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.698-78109T>C | Intron (SNP) | VAF 11/100 reads (11%) | called by muse, mutect2, varscan2
- PTPRR | c.628-336G>A | Intron (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
